Somatic mutation profile of tumor specimen TARGET-10-PARKEN-03A (aliquot TARGET-10-PARKEN-03A-01D) from TARGET case TARGET-10-PARKEN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (608 days).
Specimen TARGET-10-PARKEN-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05b4257e-2a85-4002-9de5-59eb3abd771e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARKEN-10A (Blood Derived Normal), aliquot TARGET-10-PARKEN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4362d3ac-dcc6-420c-9f93-f285e8c157db

The open-access MAF lists 10 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 3, 3'UTR 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 14/56 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SPTBN2 | c.6433G>T p.D2145Y | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.232); called by muse, mutect2
- ZNF385D | c.392T>G p.F131C | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ACTN2 | c.1299G>A p.S433= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as rs1161300633, COSV63976613; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNDP1 | c.262C>T p.L88= | Silent (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- MAGI1 | c.2910C>T p.D970= (on ENST00000402939 / NM_001033057.2; = p.D998= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs752133128, COSV100438950; called by muse, mutect2, varscan2
- ZFPM2 | c.2535G>A p.T845= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as rs772013671, COSV65873107; called by muse, mutect2, varscan2
- CAB39L | c.-179G>A | 5'UTR (SNP) | VAF 47/107 reads (44%) | catalogued as rs201608813; called by muse, mutect2, varscan2
- MORN1 | c.*7G>A | 3'UTR (SNP) | VAF 10/24 reads (42%) | catalogued as rs573677903; called by muse, mutect2
- VENTXP1 | n.642C>G | RNA (SNP) | VAF 15/29 reads (52%) | catalogued as rs1469152163; called by muse, mutect2, varscan2
